Gene-level copy-number profile of tumor specimen TCGA-EJ-7789-01A from TCGA case TCGA-EJ-7789, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,107 days).
Specimen TCGA-EJ-7789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.14c664ab-ffc0-44c5-8b63-0ff7ae320e19.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7789-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de25fa80-bd10-4b9e-ba63-5d638534e304

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 153; copy number 1: 8,309; copy number 2: 40,308; copy number 3: 9,140; copy number 4: 649; copy number 5: 66; copy number 6: 1,188.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7789-01A-11D-2112-01): tumor purity 0.98, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:115,468,056–117,539,464, 12 genes: RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1.
- chr2:133,554,315–133,558,227, 1 gene: AC011243.1.
- chr2:134,718,188–135,047,468, 8 genes (within-gene range 0–1): AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19.
- chr10:55,667,341–55,746,908, 2 genes: GAPDHP21, AC069545.1.
- chr13:60,396,457–60,613,734, 2 genes (within-gene range 0–1): TDRD3, RNA5SP31.
- chr13:60,636,888–60,638,097, 1 gene: EIF4A1P6.
- chr18:51,346,249–52,339,025, 9 genes (within-gene range 0–1): LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes: AC011155.1, VN1R76P.
- chr18:53,480,825–53,629,990, 3 genes: LINC01917, LINC01919, RPL29P32.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,254 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,918,140–186,289,681, 11 genes, copy number 5: AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11.
- chr4:186,326,302–186,336,662, 2 genes, copy number 5 (within-gene range 2–5): AC109517.1, SLC25A5P6.
- chr8:150,584–2,035,587, 45 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1.
- chr8:12,945,642–15,238,431, 24 genes, copy number 6 (within-gene range 1–6): TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr8:15,325,296–16,000,324, 7 genes, copy number 6: AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2.
- chr8:46,028,804–85,540,511, 588 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr8:87,974,165–108,083,642, 344 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr8:108,871,128–115,809,673, 45 genes, copy number 6 (within-gene range 1–6): AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1.
- chr8:116,938,207–128,564,679, 180 genes, copy number 6 (broad region; genes not listed).
- chr9:117,197,118–117,685,588, 5 genes, copy number 5: RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22.
- chr9:117,704,175–117,879,988, 3 genes, copy number 5 (within-gene range 3–5): TLR4, RNU6-1082P, AL160272.1.

Autosomal genes at a single copy (total copy number 1): 6,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
